Somatic mutation profile of tumor specimen MP2PRT-PAUCBN-TMP1-A (aliquot MP2PRT-PAUCBN-TMP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PAUCBN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.4 years (2,354 days).
Specimen MP2PRT-PAUCBN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de124d4b-2c75-4124-bbe3-cd7baf6607b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUCBN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUCBN-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f653401f-bcdd-4561-adb3-c47492b8709c

The open-access MAF lists 27 somatic variants for this specimen: 18 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 8, Frame Shift Ins 2, Intron 1, Frame Shift Del 1, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACOX1 | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 96/390 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140541455; called by muse, mutect2, varscan2
- CCDC88C | c.1346C>T p.S449F | Missense Mutation (SNP) | VAF 114/299 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1488267003; called by muse, mutect2, varscan2
- CREBBP | c.4307G>A p.S1436N | Missense Mutation (SNP) | VAF 92/269 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV52119405, COSV52136794; called by muse, mutect2, varscan2
- IQCH | c.1297C>T p.R433* | Nonsense Mutation (SNP) | VAF 82/231 reads (35%) | catalogued as rs765751827, COSV60052905; called by muse, mutect2, varscan2
- LZTR1 | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 113/308 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.938); catalogued as rs935736801, COSV53151511; called by muse, mutect2, varscan2
- MON1A | c.49C>T p.L17F | Missense Mutation (SNP) | VAF 194/714 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1315102467; called by muse, mutect2, varscan2
- MYH2 | c.3425G>A p.R1142H | Missense Mutation (SNP) | VAF 159/762 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); catalogued as rs781136210, COSV55442072; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NKX2-8 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 176/684 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs754060526; called by muse, mutect2, varscan2
- PIGT | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 209/532 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.089); catalogued as COSV54128488; called by muse, mutect2, varscan2
- RAB31 | c.67G>A p.V23M | Missense Mutation (SNP) | VAF 107/386 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs777324389, COSV71261951; called by muse, mutect2, varscan2
- TRIM71 | c.1750C>T p.R584C | Missense Mutation (SNP) | VAF 27/597 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as COSV67471858; called by muse, mutect2
- ANKRD30A | c.2563del p.S855Lfs*7 (on ENST00000611781; = p.S799Lfs*7 on NM_052997.2) | Frame Shift Del (DEL) | VAF 12/130 reads (9%) | called by mutect2, pindel
- CELSR3 | c.425G>A p.C142Y | Missense Mutation (SNP) | VAF 227/576 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ETV6 | c.300_301dup p.D101Gfs*22 | Frame Shift Ins (INS) | VAF 102/347 reads (29%) | called by mutect2, pindel, varscan2
- IGLV4-60 | c.341_361delinsTTCGGG p.E114_T120delinsVR | In Frame Del (DEL) | VAF 63/213 reads (30%) | called by pindel, varscan2*
- KCNH7 | c.1636G>C p.E546Q | Missense Mutation (SNP) | VAF 14/504 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2
- RASD1 | c.731_732insGGGAC p.I245Gfs*89 | Frame Shift Ins (INS) | VAF 232/1075 reads (22%) | called by mutect2, pindel, varscan2
- STPG2 | c.1049T>A p.I350N | Missense Mutation (SNP) | VAF 74/209 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CFAP74 | c.702C>T p.L234= | Silent (SNP) | VAF 155/376 reads (41%) | catalogued as rs369880126, COSV54565001; called by muse, mutect2, varscan2
- IGLL5 | c.261G>T p.G87= | Silent (SNP) | VAF 28/564 reads (5%) | called by muse, mutect2
- KCND2 | c.1020A>T p.T340= | Silent (SNP) | VAF 16/454 reads (4%) | called by muse, mutect2
- MANEAL | c.108G>A p.P36= | Silent (SNP) | VAF 210/552 reads (38%) | called by muse, mutect2, varscan2
- MAP3K7CL | c.441G>A p.P147= | Silent (SNP) | VAF 69/565 reads (12%) | catalogued as rs778491772, COSV54509324; called by muse, mutect2, varscan2
- PMP22 | c.384G>A p.S128= | Silent (SNP) | VAF 174/664 reads (26%) | catalogued as rs757027432, COSV56603120; called by muse, mutect2, varscan2
- SLC12A8 | c.573C>T p.A191= | Silent (SNP) | VAF 127/377 reads (34%) | catalogued as rs201127098; called by muse, mutect2, varscan2
- ZBTB7A | c.1086C>T p.G362= | Silent (SNP) | VAF 20/676 reads (3%) | catalogued as rs998860497; called by muse, mutect2
- EYS | c.1766+2596T>C | Intron (SNP) | VAF 72/214 reads (34%) | called by muse, mutect2, varscan2
